TCGA case TCGA-39-5011 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5845fe49-f2cc-436b-9ec8-65e775eae111

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,788 days); Year of diagnosis: 2002; AJCC staging edition: 6th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 4,053 days (11.1 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 580 days (1.6 years); Days to treatment end: 621 days (1.7 years); Number of cycles: 2; Treatment dose: 400 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 580 days (1.6 years); Days to treatment end: 621 days (1.7 years); Number of cycles: 2; Treatment dose: 156 mg; Prescribed dose: 78; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 580 days (1.6 years); Days to treatment end: 633 days (1.7 years); Treatment dose: 6,900 cGy; Course number: 1; Number of fractions: 36; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 677 days (1.9 years); Days to treatment end: 677 days (1.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 728 days (2.0 years); Days to treatment end: 742 days (2.0 years); Number of cycles: 3; Treatment dose: 144 mg; Prescribed dose: 48; Prescribed dose units: mg; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.2 years (26,353 days); Days to diagnosis: 565 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 565 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,454 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 4,053 days (11.1 years); Disease response: Tumor Free.

Other clinical attributes
- DLCO (% of predicted): 75; FEV1/FVC before bronchodilator (%): 66; FEV1 after bronchodilator (% of reference): 72; FEV1 before bronchodilator (% of reference): 63.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 45; Tobacco smoking quit year: 1995.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-39-5011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.1; Intermediate dimension: 1.4; Shortest dimension: 0.4.
  Slide TCGA-39-5011-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
  Slide TCGA-39-5011-01A-01-TS1: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 4; Percent stromal cells: 6; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2.
- Sample TCGA-39-5011-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-39-5011-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1.6; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Taxol; Therapy regimen: Recurrence.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,053 days; disease-specific survival: no event (censored), 4,053 days; disease-free interval: event (new tumor event after initially disease-free), 565 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 565 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-39-5011-01A-01D-1439-01): tumor purity 0.43, ploidy 1.57, whole-genome doublings 0.
